Somatic mutation profile of tumor specimen TCGA-GU-A763-01A (aliquot TCGA-GU-A763-01A-11D-A32B-08) from TCGA case TCGA-GU-A763, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 72.6 years (26,527 days).
Specimen TCGA-GU-A763-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7f29586-4614-4f8e-9565-486bb255966e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GU-A763-10A (Blood Derived Normal), aliquot TCGA-GU-A763-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/562ee140-0d89-4fbc-9155-d4ff6e1fbf04

The open-access MAF lists 73 somatic variants for this specimen: 53 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 43, Silent 20, Nonsense Mutation 6, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.15535C>T p.R5179C | Missense Mutation (SNP) | VAF 13/23 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs794727688, CM1410247, COSV56425613, COSV56431676; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAP2 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.127); catalogued as COSV58296189; called by muse, mutect2, varscan2
- AHNAK2 | c.6662T>A p.L2221H | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60917943; called by muse, mutect2, varscan2
- ALDH1L2 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99310990; called by muse, mutect2, varscan2
- ALG10B | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV58143531; called by muse, mutect2, varscan2
- AMDHD1 | c.1102A>G p.I368V | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs1565979946, COSV57139159; called by muse, mutect2, varscan2
- ATP7A | c.2335A>G p.T779A | Missense Mutation (SNP) | VAF 83/86 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58447655; called by muse, mutect2, varscan2
- BANF1 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56463749; called by muse, mutect2, varscan2
- CARM1 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 15/113 reads (13%) | catalogued as COSV100498993; called by muse, mutect2, varscan2
- CDK13 | c.2447C>A p.S816* | Nonsense Mutation (SNP) | VAF 58/146 reads (40%) | catalogued as COSV51695871, COSV99475472; called by muse, mutect2, varscan2
- CFAP44 | c.2576G>A p.G859E | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55612241; called by muse, mutect2, varscan2
- CFAP44 | c.2575G>T p.G859* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | catalogued as COSV99869444; called by muse, mutect2, varscan2
- CHD5 | c.494G>A p.S165N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV52416695; called by muse, mutect2, varscan2
- COL14A1 | c.2543C>T p.T848M | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs369592872; called by muse, mutect2, varscan2
- CRYBG3 | c.6313C>T p.P2105S | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51712631, COSV99477074; called by muse, mutect2, varscan2
- DEPDC4 | c.25C>A p.R9S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.013); catalogued as COSV54553783; called by muse, mutect2, varscan2
- FBN2 | c.6533G>A p.S2178N | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52519670; called by muse, mutect2, varscan2
- GAR1 | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as COSV56993156; called by muse, mutect2, varscan2
- GCC2 | c.2746A>G p.K916E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV59177081; called by muse, mutect2, varscan2
- HSP90AB1 | c.2035C>G p.R679G | Missense Mutation (SNP) | VAF 174/409 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV51488135, COSV51489868; called by muse, mutect2, varscan2
- IFNG | c.168G>C p.L56F | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV99971153; called by muse, mutect2, varscan2
- INO80 | c.3916G>C p.E1306Q | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.932); catalogued as COSV62738848; called by muse, mutect2, varscan2
- IQGAP3 | c.3527A>G p.Y1176C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100752137; called by muse, mutect2
- KCNK10 | c.704C>G p.S235* | Nonsense Mutation (SNP) | VAF 49/100 reads (49%) | catalogued as COSV56639511; called by muse, mutect2, varscan2
- KCNMB2 | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV100844020, COSV64201137; called by muse, mutect2, varscan2
- MDGA2 | c.1957C>T p.R653W (on ENST00000399232 / NM_001113498.2; = p.R355W on NM_182830.4) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs754861387, COSV62078505; called by muse, mutect2, varscan2
- MYCBP2 | c.2557G>C p.E853Q (on ENST00000357337; = p.E891Q on NM_015057.5) | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.954); catalogued as COSV62022844; called by muse, mutect2, varscan2
- MYH3 | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as COSV56866123, COSV99878485; called by muse, mutect2, varscan2
- MYLK | c.2237G>A p.G746D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765847503, COSV60612456; called by muse, mutect2, varscan2
- MYRF | c.853C>A p.L285M (on ENST00000278836 / NM_001127392.3; = p.L276M on NM_013279.4) | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.641); catalogued as COSV53889845; called by muse, mutect2
- NUP98 | c.2548G>A p.G850R | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61433121; called by muse, mutect2, varscan2
- OR6N1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs201930900, COSV100625158; called by muse, varscan2
- PCDH1 | c.2393G>A p.G798D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1313873398; called by muse, mutect2
- PCDHB14 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as rs1221254588, COSV53386720; called by muse, mutect2
- PHF14 | c.2063G>A p.R688K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780512816, COSV68855656; called by muse, varscan2
- PRR5-ARHGAP8 | c.1495C>G p.L499V (on ENST00000352766; = p.L420V on NM_181334.5) | Missense Mutation (SNP) | VAF 89/183 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.223); catalogued as COSV61234292; called by muse, mutect2, varscan2
- PSME4 | c.3863G>A p.G1288D | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV66365593, COSV66367499; called by muse, mutect2, varscan2
- PTBP2 | c.1196-11_1196-1del p.X399_splice (on ENST00000426398 / NM_001300986.2; = p.X391_splice on NM_021190.4) | Splice Site (DEL) | VAF 11/38 reads (29%) | catalogued as COSV64624816; called by mutect2, pindel, varscan2
- RXFP4 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs200081325; called by muse, mutect2, varscan2
- RYR3 | c.2387G>T p.G796V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212661, COSV66810690; called by muse, mutect2
- SETX | c.5189C>G p.S1730* | Nonsense Mutation (SNP) | VAF 31/34 reads (91%) | catalogued as COSV99809613, COSV99810583; called by muse, mutect2, varscan2
- SLC3A2 | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV58603794; called by muse, mutect2, varscan2
- TDRD5 | c.2774G>A p.R925H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs570123255, COSV54242186; called by muse, varscan2
- TOR3A | c.598A>C p.T200P | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV61680301; called by muse, mutect2, varscan2
- TRIML1 | c.1027T>C p.W343R | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60194693; called by muse, mutect2, varscan2
- USP3 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV51427469; called by muse, mutect2, varscan2
- WASHC4 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV59890152; called by muse, mutect2, varscan2
- XIRP2 | c.25C>T p.R9C (on ENST00000628543; = p.R184C on NM_152381.6) | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs369322473; called by muse, mutect2, varscan2
- ZSCAN5A | c.1332C>A p.D444E | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV54227589; called by muse, mutect2, varscan2
- AFF3 | c.672del p.S225Afs*11 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- DNAJC3 | c.231_250del p.R77Sfs*10 | Frame Shift Del (DEL) | VAF 38/120 reads (32%) | called by mutect2, pindel*, varscan2*
- SMARCA1 | c.3080dup p.N1027Kfs*5 | Frame Shift Ins (INS) | VAF 33/46 reads (72%) | called by mutect2, pindel, varscan2
- ACADS | c.1002G>A p.L334= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV54369182; called by muse, mutect2
- AEN | c.693G>A p.R231= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as rs1422202919, COSV60429564; called by muse, mutect2, varscan2
- AMER1 | c.2226G>A p.R742= | Silent (SNP) | VAF 27/28 reads (96%) | catalogued as COSV57661989; called by muse, mutect2, varscan2
- ATP8A2 | c.180C>T p.L60= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV54956873; called by muse, mutect2, varscan2
- CARM1 | c.396G>T p.L132= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV58999571, COSV59000898; called by muse, mutect2, varscan2
- CDYL2 | c.480C>T p.D160= | Silent (SNP) | VAF 44/98 reads (45%) | catalogued as rs746532742, COSV73647705; called by muse, mutect2, varscan2
- FAM117B | c.1542C>A p.L514= | Silent (SNP) | VAF 70/155 reads (45%) | catalogued as rs938931875, COSV57419677, COSV57423091; called by muse, mutect2, varscan2
- GDF3 | c.594C>T p.F198= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs754962446, COSV61712314; called by muse, mutect2, varscan2
- HIVEP1 | c.4923G>A p.Q1641= | Silent (SNP) | VAF 53/126 reads (42%) | catalogued as rs1342592708, COSV65102352; called by muse, mutect2, varscan2
- LARP4 | c.180C>G p.L60= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV53323361; called by muse, mutect2, varscan2
- MUC16 | c.11799C>T p.A3933= | Silent (SNP) | VAF 17/27 reads (63%) | catalogued as rs754122574, COSV67472554; called by muse, mutect2, varscan2
- MYH14 | c.4431G>A p.E1477= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV51820738; called by mutect2, varscan2
- MYRF | c.852C>A p.A284= (on ENST00000278836 / NM_001127392.3; = p.A275= on NM_013279.4) | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as COSV53889826; called by muse, mutect2
- NUP153 | c.2509C>T p.L837= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV50451039; called by muse, mutect2, varscan2
- PCDHB9 | c.390G>A p.S130= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as COSV53383201; called by muse, mutect2, varscan2
- PLEC | c.1788C>T p.L596= (on ENST00000322810 / NM_201380.4; = p.L486= on NM_000445.5) | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs1298888541, COSV59647020; called by muse, mutect2, varscan2
- SERPINA1 | c.288T>G p.T96= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV63345765; called by muse, mutect2, varscan2
- SPG7 | c.1587A>G p.G529= (on ENST00000268704; = p.G536= on NM_003119.4) | Silent (SNP) | VAF 67/154 reads (44%) | catalogued as COSV51951302; called by muse, mutect2, varscan2
- TMEM108 | c.753G>A p.Q251= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV58870238, COSV58873635; called by muse, mutect2, varscan2
- ZNF226 | c.585A>G p.K195= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV100335289, COSV56196869; called by muse, mutect2, varscan2
